Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96H, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96H-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

tumor: 4.0 x 2.5 x 2.0 cm

Diagnosis:

Type A-Thymoma

pT2

Masaoka: II

focal infiltration of mediastinal fat tissue

Immunohistochemistry

epithelial cells positive for: CK 5/6

in between epithelial cells some CD99-positive immature T-lymphocytes

ICD-O-3
Thymoma, Type A,
malignant 8581/3
Site: Thymus C39.9
QW 4/7/14

Source: NCI Genomic Data Commons file 506bdb05-6e4f-4a7e-b4f8-b7764521f598 (TCGA-ZB-A96H.EB51C592-0BFA-4A5B-A4CE-D26DE6B510BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).